Somatic mutation profile of tumor specimen MP2PRT-PAVRPK-TMP1-A (aliquot MP2PRT-PAVRPK-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVRPK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,835 days).
Specimen MP2PRT-PAVRPK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf8e326f-bc9d-42cb-a98f-c94fe0e3718c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVRPK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVRPK-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81422225-14db-47c3-b8ed-9a26e5502386

The open-access MAF lists 53 somatic variants for this specimen: 42 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 38, Silent 11, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP7B1 | c.1354C>T p.R452* | Nonsense Mutation (SNP) | VAF 112/275 reads (41%) | catalogued as rs769676029, COSV59592240; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.3330G>A p.R1110= | Splice Region (SNP) | VAF 75/201 reads (37%) | catalogued as rs140311333; called by muse, mutect2, varscan2
- ANO5 | c.688G>C p.D230H | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV61083312; called by muse, mutect2, varscan2
- CHPF | c.2026G>C p.E676Q | Missense Mutation (SNP) | VAF 16/437 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60536052; called by muse, mutect2
- DAP3 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 23/300 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs766644128; called by muse, mutect2
- DEPDC5 | c.1813C>T p.R605W | Missense Mutation (SNP) | VAF 129/334 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1335111412; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLC1 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 107/294 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs556089862; called by muse, mutect2, varscan2
- ECEL1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 191/393 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as rs1278509874; called by muse, mutect2, varscan2
- ELL | c.956C>G p.S319W | Missense Mutation (SNP) | VAF 120/289 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV53210836, COSV53213989; called by muse, mutect2, varscan2
- MTCH2 | c.355C>G p.H119D | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV99043714; called by muse, varscan2
- NSD2 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 117/227 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56386357; called by muse, mutect2, varscan2
- PCDHB2 | c.1609G>C p.D537H | Missense Mutation (SNP) | VAF 358/763 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50571388, COSV50577712; called by muse, mutect2, varscan2
- POLDIP2 | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 85/212 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.097); catalogued as rs374709330; called by muse, mutect2, varscan2
- PRKDC | c.11119G>A p.G3707S | Missense Mutation (SNP) | VAF 121/283 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1054042388; called by muse, mutect2, varscan2
- RPS6KB1 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 90/206 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV99847246; called by muse, mutect2, varscan2
- SACS | c.4249G>C p.E1417Q | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV66537779; called by muse, mutect2
- SEC31A | c.1147C>G p.L383V | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV52348306; called by muse, mutect2
- SYNE1 | c.6559G>C p.E2187Q (on ENST00000367255 / NM_182961.4; = p.E2194Q on NM_033071.3) | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV99551823; called by muse, mutect2, varscan2
- TULP4 | c.1332G>T p.M444I | Missense Mutation (SNP) | VAF 158/347 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.937); catalogued as COSV65582326; called by muse, mutect2, varscan2
- ADGRF1 | c.1986C>G p.F662L | Missense Mutation (SNP) | VAF 123/282 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARIH2 | c.786G>T p.Q262H | Missense Mutation (SNP) | VAF 89/203 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- CDH1 | c.1045G>C p.D349H | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLG4 | c.2135C>G p.S712* (on ENST00000399506 / NM_001321075.3; = p.S755* on NM_001365.4) | Nonsense Mutation (SNP) | VAF 132/336 reads (39%) | called by muse, mutect2, varscan2
- DNAH17 | c.9546G>C p.K3182N | Missense Mutation (SNP) | VAF 134/333 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- F2RL1 | c.127G>C p.D43H | Missense Mutation (SNP) | VAF 87/215 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FANCB | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 149/328 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSCB | c.1297C>G p.P433A | Missense Mutation (SNP) | VAF 129/272 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ITGBL1 | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LMBRD1 | c.835G>T p.D279Y (on ENST00000649011; = p.D257Y on NM_018368.4) | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MCM10 | c.857G>C p.R286T (on ENST00000484800 / NM_182751.3; = p.R285T on NM_018518.5) | Missense Mutation (SNP) | VAF 150/336 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED13L | c.2450C>G p.S817C | Missense Mutation (SNP) | VAF 91/207 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- NEIL3 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- NXF1 | c.1844_1845insC p.A616Gfs*17 | Frame Shift Ins (INS) | VAF 136/312 reads (44%) | called by mutect2, pindel*, varscan2
- P2RY13 | c.294C>G p.F98L | Missense Mutation (SNP) | VAF 117/144 reads (81%) | SIFT tolerated (0.2); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- PHF8 | c.844T>A p.F282I (on ENST00000357988 / NM_001184896.1; = p.F246I on NM_015107.3) | Missense Mutation (SNP) | VAF 19/369 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- RBM15 | c.1793C>T p.T598I | Missense Mutation (SNP) | VAF 113/296 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIX4 | c.928C>G p.H310D | Missense Mutation (SNP) | VAF 144/345 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SMAD6 | c.850C>G p.P284A | Missense Mutation (SNP) | VAF 131/292 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- ST14 | c.1297C>G p.Q433E | Missense Mutation (SNP) | VAF 162/394 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TGM2 | c.1830G>C p.Q610H | Missense Mutation (SNP) | VAF 179/411 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TTN | c.22277G>T p.R7426I (on ENST00000591111; = p.R6499I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/176 reads (14%) | PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- ZNF883 | c.977G>T p.C326F | Missense Mutation (SNP) | VAF 120/264 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSL4 | c.1200C>T p.F400= (on ENST00000340800 / NM_022977.2; = p.F359= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV100538315; called by muse, mutect2, varscan2
- AKAP6 | c.4965T>C p.S1655= | Silent (SNP) | VAF 27/273 reads (10%) | catalogued as COSV55209238; called by muse, mutect2, varscan2
- ELL | c.990C>T p.F330= | Silent (SNP) | VAF 107/248 reads (43%) | catalogued as COSV99443504; called by muse, mutect2, varscan2
- GRIN1 | c.2490G>C p.L830= | Silent (SNP) | VAF 141/312 reads (45%) | catalogued as rs200898441; called by muse, mutect2, varscan2
- KCP | c.4053G>A p.L1351= (on ENST00000620378; = p.L1475= on NM_001366122.1) | Silent (SNP) | VAF 237/482 reads (49%) | called by muse, mutect2, varscan2
- MAP1B | c.51C>T p.I17= | Silent (SNP) | VAF 147/349 reads (42%) | called by muse, mutect2, varscan2
- MUC17 | c.3297A>G p.G1099= | Silent (SNP) | VAF 147/631 reads (23%) | called by muse, mutect2, varscan2
- NBEA | c.8700C>T p.Y2900= | Silent (SNP) | VAF 120/284 reads (42%) | called by muse, mutect2, varscan2
- NPTX1 | c.15C>T p.R5= | Silent (SNP) | VAF 43/230 reads (19%) | called by muse, mutect2, varscan2
- SYT13 | c.153G>A p.A51= | Silent (SNP) | VAF 34/550 reads (6%) | catalogued as rs573392398, COSV50072925; called by muse, mutect2
- ZNF792 | c.111C>G p.L37= | Silent (SNP) | VAF 39/274 reads (14%) | called by muse, mutect2, varscan2
